Somatic mutation profile of tumor specimen e5e1306b-719e-4c3e-b85b-fd1231 (aliquot e5e1306b-719e-4c3e-b85b-fd1231_D6_1) from CPTAC case 01BR032, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 42.0 years (15,329 days).
Specimen e5e1306b-719e-4c3e-b85b-fd1231: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6ad82a3-a64d-4b3f-ae05-fa686bc566c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 67ebb699-4493-40ac-8aa2-2e7852 (Blood Derived Normal), aliquot 67ebb699-4493-40ac-8aa2-2e7852_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5abbf5d-a4a4-429c-aab6-c210bda49b80

The open-access MAF lists 44 somatic variants for this specimen: 24 protein-altering or splice-affecting, 13 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 13, 5'Flank 3, Nonsense Mutation 2, Intron 2, 3'UTR 1, In Frame Del 1, Frame Shift Ins 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP2A6 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs372113929; called by muse, mutect2, varscan2
- EXOC7 | c.1004G>T p.R335L | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.968); catalogued as rs911250370; called by mutect2, varscan2
- HOXB8 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as rs774570857, COSV99494082; called by muse, mutect2, varscan2
- PBX2 | c.130dup p.V44Gfs*46 | Frame Shift Ins (INS) | VAF 24/68 reads (35%) | catalogued as rs747720400; called by mutect2, varscan2
- PLA2G2E | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as rs762351431; called by muse, mutect2, varscan2
- SLC16A3 | c.818T>C p.I273T | Missense Mutation (SNP) | VAF 76/187 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as rs201751464; called by muse, mutect2, varscan2
- SOX8 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as rs556723952, COSV53508927; called by muse, mutect2, varscan2
- TNR | c.1304G>A p.W435* | Nonsense Mutation (SNP) | VAF 101/351 reads (29%) | catalogued as COSV54894092; called by muse, mutect2, varscan2
- ARMC2 | c.2601C>A p.F867L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, varscan2
- CACUL1 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDT1 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- CLIP2 | c.2564C>A p.A855E | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.69); called by muse, varscan2
- EXPH5 | c.2926A>G p.I976V | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FOXO3 | c.353_359del p.G118Afs*46 | Frame Shift Del (DEL) | VAF 10/16 reads (63%) | called by mutect2, varscan2
- GATA3 | c.1070A>C p.K357T | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPANK1 | c.250_264del p.V84_A88del | In Frame Del (DEL) | VAF 115/287 reads (40%) | called by mutect2, pindel, varscan2
- LRP2 | c.13063C>T p.Q4355* | Nonsense Mutation (SNP) | VAF 22/754 reads (3%) | called by muse, mutect2
- NEO1 | c.1956T>G p.I652M | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- RC3H1 | c.1265T>G p.M422R | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- SCUBE2 | c.449A>T p.Y150F | Missense Mutation (SNP) | VAF 84/184 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC39A10 | c.1198G>C p.A400P | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TAOK1 | c.2516C>G p.S839C | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- TMPRSS9 | c.3072C>A p.S1024R (on ENST00000648592; = p.S990R on NM_182973.2) | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- USP8 | c.2221A>C p.N741H | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- BTBD7 | c.1308G>A p.S436= | Silent (SNP) | VAF 99/235 reads (42%) | catalogued as rs1480510990, COSV100598280; called by muse, mutect2, varscan2
- EXOC6B | c.1597T>C p.L533= | Silent (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- FBXO11 | c.918C>T p.I306= (on ENST00000403359 / NM_001190274.2; = p.I222= on NM_025133.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs748109070; called by muse, mutect2, varscan2
- FCRL4 | c.1503A>G p.P501= | Silent (SNP) | VAF 18/457 reads (4%) | called by muse, mutect2
- HTR2C | c.420G>A p.A140= | Silent (SNP) | VAF 12/170 reads (7%) | catalogued as rs200457900, COSV52213029; called by muse, mutect2
- NCOA6 | c.2742G>A p.P914= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as rs759134877; called by muse, mutect2, varscan2
- PKNOX1 | c.618G>A p.V206= | Silent (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- PLA2R1 | c.4164G>A p.A1388= | Silent (SNP) | VAF 55/141 reads (39%) | catalogued as rs775874050; called by muse, mutect2, varscan2
- PRRG3 | c.384C>A p.T128= | Silent (SNP) | VAF 150/368 reads (41%) | called by muse, varscan2
- RREB1 | c.2484C>T p.A828= | Silent (SNP) | VAF 95/183 reads (52%) | catalogued as rs1245935076, COSV58565645; called by muse, mutect2, varscan2
- SLC3A1 | c.1119G>A p.T373= | Silent (SNP) | VAF 105/293 reads (36%) | catalogued as rs772223467; called by muse, mutect2, varscan2
- SNX15 | c.744C>G p.P248= | Silent (SNP) | VAF 53/119 reads (45%) | called by muse, mutect2, varscan2
- TLR8 | c.3039G>A p.L1013= (on ENST00000218032 / NM_138636.5; = p.L1031= on NM_016610.4) | Silent (SNP) | VAF 23/153 reads (15%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502977 A>G | 5'Flank (SNP) | VAF 48/94 reads (51%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499835 ins TAGAAGAAAA | 5'Flank (INS) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- CA2 | chr8:85463992 G>A | 5'Flank (SNP) | VAF 65/160 reads (41%) | called by muse, mutect2, varscan2
- CC2D2A | c.123+423A>G | Intron (SNP) | VAF 36/366 reads (10%) | catalogued as rs749544343; called by muse, mutect2, varscan2
- LINC01001 | n.484G>C | RNA (SNP) | VAF 7/61 reads (11%) | catalogued as rs61869653; called by muse, mutect2
- PDCD6 | c.*94G>A | 3'UTR (SNP) | VAF 90/232 reads (39%) | called by muse, varscan2
- SUN1 | c.452-13_452-12insGTG | Intron (INS) | VAF 17/68 reads (25%) | catalogued as rs537734027, COSV61779091; called by pindel, varscan2
